Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A80O, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A80O-01A (Primary Tumor).

Material:
Adrenal

Clinical data:
Suspected Pheochromocytoma.
Question: Pheo? Malignant?

Description material: left adrenal gland.

Macroscopy

Fresh: adrenal, weight of 75 grams and with dimensions of 7.5 x 5.0 x 4.0 cm
A fragment of the tumor is frozen. Afterwards on formalin.
Rest macro follows.

On formalin a left adrenal, already halved. Herein a nodule palpable, with dimensions of approximately 4,5 x 5 x 4 cm. Preparation is laminated. In total there are 16 laminas, in lamina 7 t/m 16 is a tumor with a maximum diameter of 4 cm. On section there is steel normal adrenal tissue seen.

The tumor includes cystic defects, hemorrhage and calcification. The tumor is completely encapsulated. The tumor presented in several places to about 1 mm of the resection plane.

Cassette 1: Beginning of the tumor with normal adrenal gland.

Cassette 2 and 3: lamina 11 with tumor and most endangered resection.

Cassette 4 and 5: lamina 14 with tumor and most endangered resection.

Vulpian reaction was negative. Partially 5b.

Microscopy

Adrenal Preparation of adrenal with on the one hand normal adrenal layered epithelium, on the other hand, as described by macroscopic fibrous capsule of the partially polymorphic round or angular nuclei with finely granular chromatin and conspicuous nucleoli, and eosinophilic cytoplasm with over here and there eosinophilic inclusions. Also polynuclear tumor cells with hyperchromatic nuclei. Between the fields partly thin, partly sinusoidal dilated capillaries, barely stroma. Or focal haemorrhage and hyaline fibrosis. (Sections 2.3 and 5). The tumor appears to focal pseudo capsule and infiltrate the adjacent fat (Compartment 1). Between vital tumor and outside at least 1 mm connective tissue and fat. Internal consulting: concordant. No mitoses found no obvious necrosis.

Conclusion

Tentative: Extirpation of left adrenal pheochromocytoma with maximum 4 cm diameter, tight but completely removed (minimum margin 1 mm).

SUPPLEMENTARY focal haircut breakthrough with invasion of surrounding adipose tissue.
No angio-invasion, no necrosis, no mitoses.

ICD-O-3

Pheochromocytoma NOS
8700/0

Site Adrenal gland NOS
C74.9

9/10/13

Criteria	met 9/28/13	Yes	No
HWA Discrepancy			

Source: NCI Genomic Data Commons file 8aee370a-9b1a-4ddd-b81e-f64b72bdc09f (TCGA-WB-A80O.75E22C35-6B62-4A2C-8510-81B598E0FD73.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).